Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB35, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB35-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

ICD.O.3
Liposarcoma, dedifferentiated
8858/3
Site: Colon 18.6
J 3/10/14

Clinical Diagnosis & History:

History of retroperitoneal liposarcoma initially , status post resection now with recurrence.

Specimens Submitted:

- 1: Left radical nephrectomy left colectomy resection of psas and illiacus muscle
- 2: Small bowel
- 3: Mesenteric nodule
- 4: Abdominal scar

DIAGNOSIS:

1. Left nephrectomy left colectomy resection of psas and illiacus muscle, radical resection:
- Recurrent high grade dedifferentiated liposarcoma, involving left colon wall, encasing left kidney and ureter.
- The tumor has a multinodular growth pattern, the largest nodule measuring 18.5 x 15.5 x 12.0 cm.
- The dedifferentiated component shows a high grade myxofibrosarcoma-like morphology, comprising >50% of the mass.
- Tumor necrosis is present, estimated as 25% grossly.
- Tumor is surrounded grossly by a thin membrane which represents the surgical resection margin.
- Colon, ureter, and renal vascular margins are free of tumor.
- Muscle tissue is not involved by tumor.
- Renal parenchyma with glomerulosclerosis and non-specific interstitial inflammation.
2. Small bowel, resection:
- Focal areas of scarring.
- Serosa with fibrosis, adhesion, mild acute and chronic inflammation.
- No evidence of malignancy.
3. Soft tissue, Mesenteric nodule, biopsy:
- Nodule of mature adipose tissue with scattered hyperchromatic stromal cells, consistent with well-differentiated liposarcoma (1.2 x1.0 x 0.5 cm).
4. Abdominal scar, excision:
- Dermal scar with acute and mild chronic inflammation.

** Continued on next page **

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 4

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh and labeled "Resection of psoas and iliacus muscle, left radical nephrectomy, left colectomy". It consists of a soft tissue mass measuring 18.5 x 15.5 x 12.0 cm, a segment of colon (9.5 cm long, 5.5 cm in circumference), left kidney (9.5 x 4.5 x 3.0 cm) with attached ureter (16 cm long, 0.8 cm in diameter), and a small fragment of muscle tissue (5.5 x 3.0 x 0.8 cm). The specimen weighs 2033 grams in total. The large soft tissue mass is encapsulated by a thin layer of fibrous tissue that is easily separated from the mass. The cut surface is solid, lobulated, soft, variegated including tan-yellow, to yellow-white, to friable gray. The friable dusky area occupies roughly 25% of the mass. The mass adheres to the colon wall through its fibrous capsule without grossly invading into it. The colonic mucosa is tan-pink and flat. The mass also adheres to the distal segment of the ureter, spanning 6 cm, through its capsule. The ureter is not grossly involved by the tumor. Sectioning of the kidney and the perirenal adipose tissue reveals two additional lobulated tumors, most likely contiguous with the main mass, being attached to the lower pole and in the hilum, separated by 2.5 cm. The sizes of these nodular masses are 8.4 x 6.5 x 3.8 and 3.5 x 3.0 x 2.0 cm respectively with homogenous tan-yellow cut surface. Both are encapsulated by thin capsules. Neither of the two tumors is invading into the renal parenchyma. The renal parenchyma is thinned ranging from 1.5 to 2.5 cm. The renal pelvis and calyces are mildly dilated. The muscle tissue is attached to superior and posterior aspect of the kidney and is 2.0 cm from closest tumor. No adrenal tissue is grossly identified. The specimen is photographed. Sections of the tumor and normal kidney and perirenal fat are submitted for TPS. Representative sections are submitted for permanent.

Summary all sections:

UM - distal ureteral margin and renal vascular margin
PCM - proximal colon resection margin
DCM - distal colon resection margin
T1 - largest tumor
TC -T1 to colon
TU -T1 to ureter
M - muscle tissue
T2 - tumor attached to lower pole
T3 - renal hilar tumor
T1T2 fibroadipose tissue linked between two nodular areas
T2T3 section in between two nodular areas
K random kidney

** Continued on next page **

[page 3 of 4]
2) The specimen was received fresh, labeled "Small bowel" and consists of an unoriented segment of small bowel measuring 37.0 cm in length and ranging from 4.0 to 7.5 cm in circumference. The serosa is pink purple focally shaggy with minute areas of gray-tan fibromembranous adhesions, and minimal attached adipose tissue. Both ends are stapled shut. The specimen is opened to reveal red-brown plicated ischemic mucosa, with a wall averaging 0.4 cm in thickness. A segment of small bowel measuring 8.2 cm in length is folded back upon itself, possible an anastomosis. A 1.5 cm in greatest dimension focus of firm induration is identified 5.0 cm from one margin near the anastomosis, with a suture on the serosal surface. Representative sections are submitted.

Summary of sections:

AM - margin closest to anastomosis
OM - opposite margin
I - firm focus
RS -representative sections

3) The specimen is received fresh, labeled "mesenteric nodule", and consists of a 1.2 x 1.0 x 0.6 cm portion of tan soft tissue. The specimen is bisected and entirely submitted.

Summary of sections:

U - undesignated

4) The specimen is received fresh, labeled "abdominal scar" and consists of a gray-tan wrinkled ellipse of skin measuring 21.0 x 4.1 x 0.6 cm. A portion of the skin ellipse is firm and indurated. The specimen is representatively submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: Left radical nephrectomy left colectomy resection of psas and illiacus muscle

Block	Sect.	Site	PCs
1		DCM	1
1		M	1

** Continued on next page **

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

----- Page 4 of 4

1	PCM	1
1	R	1
10	T1	20
1	T1T2	1
5	T2	5
1	T2T3	1
2	T3	2
2	TC	2
2	TU	2
1	UM	3

Part 2: Small bowel

Block	Sect. Site	PCs
1	AM	2
1	FF	1
1	OM	2
2	RS	2

Part 3: Mesenteric nodule

Block	Sect. Site	PCs
1	U	2

Part 4: Abdominal scar

Block	Sect. Site	PCs
1	U	3

** End of Report **

Source: NCI Genomic Data Commons file bc20b851-8431-49ff-aad9-38c2bf52696d (TCGA-DX-AB35.8B242410-FD42-47A7-99E6-0E8F62807A51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).